Gene-level copy-number profile of tumor specimen C3N-03662-01 from CPTAC case C3N-03662, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.0 years (23,732 days).
Specimen C3N-03662-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba61bd69-e586-4fdf-844d-58308907ae3f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03662-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/e875d00f-c159-40b7-adc1-9eca8ae84ca7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 422; copy number 1: 266; copy number 2: 26,414; copy number 3: 7,037; copy number 4: 19,668; copy number 5: 3,187; copy number 6: 278; copy number 7: 1,314; copy number 8: 11; copy number 9: 137; copy number 11: 18; copy number 13: 68; copy number 15: 17; copy number 16: 10; copy number 18: 4; copy number 22: 45.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–143,500,512, 9 genes: AC242852.1, AC242852.2, AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr1:143,699,456–143,825,837, 10 genes: RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1.
- chr1:143,905,487–144,373,659, 12 genes (within-gene range 0–1): AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr1:161,617,992–161,631,963, 2 genes (within-gene range 0–1): RPS23P9, FCGR3B.
- chr2:140,234,737–140,234,923, 1 gene (within-gene range 0–4): AC092156.1.
- chr4:66,431,092–66,431,521, 1 gene: RPS23P3.
- chr5:63,301,523–63,302,056, 1 gene: AC025445.1.
- chr5:86,353,803–86,381,426, 2 genes: AC016550.2, AC016550.3.
- chr5:100,153,672–100,153,779, 1 gene: RNU6-1119P.
- chr5:173,314,713–174,730,896, 27 genes: STC2, MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, LINC01485, CPEB4, C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr6:49,960,249–49,964,164, 1 gene: DEFB114.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:65,189,995–65,230,861, 3 genes: BMS1P12, AL512605.1, AL512605.2.
- chr11:54,724,847–54,725,816, 1 gene: OR4A6P.
- chr11:95,768,953–95,790,409, 1 gene (within-gene range 0–2): FAM76B.
- chr14:44,077,534–44,077,884, 1 gene (within-gene range 0–2): EIF4BP1.
- chr14:83,017,106–83,018,144, 1 gene: AL359238.1.
- chr16:61,743,154–61,743,476, 1 gene (within-gene range 0–2): RN7SKP76.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,089 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,100,236–91,580,863, 17 genes, copy number 5–8: IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr2:191,792,797–192,044,525, 4 genes, copy number 6 (within-gene range 4–6): AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1.
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 7 (broad region; genes not listed).
- chr7:66,025,126–66,607,107, 24 genes, copy number 6: AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5.
- chr7:76,818,377–77,957,503, 29 genes, copy number 5: AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA.
- chr9:38,804,007–40,106,661, 26 genes, copy number 5 (within-gene range 3–5): AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene, copy number 5: RPL7AP49.
- chr9:65,287,914–65,894,790, 11 genes, copy number 5: CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3.
- chr9:66,082,350–68,540,883, 43 genes, copy number 5: SNX18P4, AL513478.1, CDRT15P12, RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1, AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3, CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1, BX664730.1, Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252.
- chr14:18,333,726–18,596,310, 8 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr14:18,614,388–18,712,643, 13 genes, copy number 7: CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr17:19,160,789–22,439,033, 152 genes, copy number 5–6 (broad region; genes not listed).
- chr18:74,073,353–75,209,139, 19 genes, copy number 7–11: FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, C18orf63, FAUP1, LINC01922, DIPK1C, CNDP2, AC009704.2, CNDP1, AC009704.1, LINC00909, ZNF407, AC015819.2, AC015819.1, AC015819.3, ZADH2.
- chr20:87,250–34,560,345, 672 genes, copy number 5–9 (broad region; genes not listed).
- chr21:7,744,962–27,751,233, 286 genes, copy number 5–22 (broad region; genes not listed).
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 73. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
